Somatic mutation profile of tumor specimen MMRF_1201_1_BM_CD138pos (aliquot MMRF_1201_1_BM_CD138pos_T1_KBS5U_L02845) from MMRF case MMRF_1201, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,577 days).
Specimen MMRF_1201_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bbc14e3-30b9-4228-aa0a-5ea44464b5c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1201_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1201_1_PB_WBC_C3_KBS5U_L02857; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/831f759f-3f26-459e-ae3d-2ec054a1e805

The open-access MAF lists 122 somatic variants for this specimen: 43 protein-altering or splice-affecting, 18 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 31, Intron 19, Silent 18, 3'Flank 4, In Frame Del 3, 5'Flank 3, 5'UTR 2, RNA 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by mutect2, varscan2
- CECR2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 41/99 reads (41%) | catalogued as rs1000953634, COSV52847831; called by muse, mutect2, varscan2
- CHRNA4 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs375524982, CM1212665, COSV64719127; called by muse, mutect2, varscan2
- CSMD3 | c.4339G>A p.V1447I (on ENST00000297405 / NM_001363185.1; = p.V1343I on NM_052900.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as rs559028004; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2
- HOXA1 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1207189382, COSV58029150; called by muse, mutect2, varscan2
- HTR1B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs750400332, COSV64051170; called by muse, mutect2, varscan2
- IGHJ5 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 35/65 reads (54%) | PolyPhen benign (0.086); catalogued as rs781822844; called by muse, varscan2
- IGHV2-70 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs368209907; called by muse, varscan2
- IGLL5 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs749763264, COSV73251006, COSV73251200; called by muse, mutect2, varscan2
- MEF2A | c.258+8A>G | Splice Region (SNP) | VAF 16/32 reads (50%) | catalogued as rs1220802225; called by muse, mutect2, varscan2
- PCDHGA4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV99542936; called by muse, mutect2
- PNMA2 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs769441970; called by muse, mutect2, varscan2
- RIT2 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs777127147, COSV100449455, COSV58676103; called by muse, mutect2, varscan2
- SCN11A | c.4433G>A p.R1478Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs758597298, COSV56577794; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.93496G>A p.D31166N (on ENST00000591111; = p.D23742N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | PolyPhen benign (0.274); catalogued as COSV60236264; called by muse, mutect2, varscan2
- ARID2 | c.627_629del p.F210del | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- CBY3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CHAF1A | c.1866C>A p.D622E | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- COL21A1 | c.2447A>C p.N816T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2
- DDX42 | c.2023A>C p.N675H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2
- DTX1 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUBP1 | c.104_120+12del p.X35_splice | Splice Site (DEL) | VAF 28/71 reads (39%) | called by mutect2, varscan2
- GIPR | c.926T>G p.I309S | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IGKC | c.322dup p.*108= | Frame Shift Ins (INS) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- MPP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OGT | c.1803_1809delinsA p.F601_V603delinsL | In Frame Del (DEL) | VAF 55/56 reads (98%) | called by pindel, varscan2*
- PIK3C2G | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PTPRQ | c.2244A>G p.I748M (on ENST00000616559; = p.I706M on NM_001145026.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by mutect2, varscan2
- PTPRQ | c.2335T>C p.Y779H (on ENST00000616559; = p.Y737H on NM_001145026.2) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); called by muse, varscan2
- PURA | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 190/284 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP2B | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2
- PYROXD1 | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RPL3 | c.478A>C p.I160L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2
- RSRP1 | c.416_430del p.Y139_R144delinsC | In Frame Del (DEL) | VAF 50/166 reads (30%) | called by pindel, varscan2
- SALL3 | c.3307G>C p.A1103P | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SHTN1 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SORL1 | c.6189G>A p.M2063I | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPATA19 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- TFAP2C | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNPO3 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- USP7 | c.2222A>T p.N741I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ABL1 | c.165C>T p.L55= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as rs1028031620; called by muse, mutect2, varscan2
- AKAP6 | c.5136G>A p.P1712= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs375264170; called by muse, mutect2, varscan2
- CLRN1 | c.564A>T p.S188= (on ENST00000327047 / NM_174878.3; = p.S112= on NM_052995.2) | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- FHOD3 | c.1056C>T p.G352= | Silent (SNP) | VAF 52/103 reads (50%) | catalogued as rs142186343; called by muse, mutect2, varscan2
- FOXRED2 | c.1554G>A p.G518= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as rs1214081729; called by muse, mutect2, varscan2
- GART | c.1350G>A p.L450= | Silent (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- GNAO1 | c.399C>T p.G133= | Silent (SNP) | VAF 86/180 reads (48%) | catalogued as rs556058539, COSV52612417; called by muse, mutect2, varscan2
- IGHV2-70D | c.303T>G p.L101= | Silent (SNP) | VAF 36/43 reads (84%) | called by muse, varscan2
- MYH6 | c.3696C>T p.D1232= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs779525060; called by muse, varscan2
- OR4C12 | c.867T>C p.N289= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1617C>T p.D539= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs782771217, COSV100247546; called by muse, mutect2, varscan2
- POLR3B | c.45G>A p.Q15= | Silent (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1278C>T p.Y426= | Silent (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- SNRNP200 | c.1542G>A p.L514= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- STXBP5L | c.1707T>C p.P569= | Silent (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- SYDE1 | c.1071C>T p.F357= | Silent (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- TSC22D1 | c.189G>C p.L63= | Silent (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- UGT2A1 | c.933C>T p.V311= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1230146326; called by muse, mutect2, varscan2
- ADGRL4 | c.*187G>T | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- AMPH | c.1183-1410C>G | Intron (SNP) | VAF 64/154 reads (42%) | called by muse, mutect2, varscan2
- BTG3 | c.*286C>T | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- C12orf56 | c.*228C>A | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- C12orf77 | n.612+213T>G | Intron (SNP) | VAF 75/137 reads (55%) | called by muse, mutect2, varscan2
- C1orf115 | c.*558G>A | 3'UTR (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- CACNA1D | c.2811+91C>T | Intron (SNP) | VAF 84/164 reads (51%) | catalogued as rs570064228; called by muse, mutect2, varscan2
- CACNB2 | c.120+235G>C | Intron (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- CCDC58 | c.*174A>C | 3'UTR (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- CDC37L1 | c.*494A>G | 3'UTR (SNP) | VAF 73/175 reads (42%) | called by muse, mutect2, varscan2
- CHCHD4 | c.-110C>A | 5'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- CSK | c.722+28T>G | Intron (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- DENND6A | c.*2606T>A | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- DUS2 | c.-18-85C>G | Intron (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- EN2 | c.*1058G>A | 3'UTR (SNP) | VAF 85/177 reads (48%) | called by muse, mutect2, varscan2
- F2RL2 | c.*43T>C | 3'UTR (SNP) | VAF 87/237 reads (37%) | called by muse, mutect2, varscan2
- FAM13A | c.605+562G>C | Intron (SNP) | VAF 72/168 reads (43%) | called by muse, mutect2, varscan2
- FAM155A | c.*247G>C | 3'UTR (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- FAM169B | n.614C>T | RNA (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85529921 G>C | 5'Flank (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- GPX5 | c.*312C>T | 3'UTR (SNP) | VAF 19/52 reads (37%) | catalogued as rs966933727; called by muse, mutect2, varscan2
- H3-2 | c.*111C>T | 3'UTR (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- ID3 | c.*25+107G>T | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, varscan2
- IER5L | c.*854C>T | 3'UTR (SNP) | VAF 78/216 reads (36%) | catalogued as rs1292748403; called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863441 T>G | 5'Flank (SNP) | VAF 6/15 reads (40%) | called by muse, varscan2
- KIDINS220 | c.3586-43T>C | Intron (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- KMO | c.*209A>T | 3'UTR (SNP) | VAF 36/51 reads (71%) | called by muse, mutect2, varscan2
- LRRC58 | c.*891A>C | 3'UTR (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2
- MEIS1 | c.-624_-621del | 5'UTR (DEL) | VAF 120/312 reads (38%) | catalogued as rs944697549; called by pindel, varscan2
- MIPOL1 | c.*626T>A | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- MKRN2 | chr3:12584996 A>C | 3'Flank (SNP) | VAF 9/207 reads (4%) | called by muse, mutect2
- MMP15 | c.*963G>A | 3'UTR (SNP) | VAF 58/141 reads (41%) | called by muse, mutect2, varscan2
- MND1 | c.*231T>C | 3'UTR (SNP) | VAF 80/153 reads (52%) | called by muse, mutect2, varscan2
- PANX1 | c.*1049C>T | 3'UTR (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-11762A>T | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- PFDN6 | chr6:33295906 A>T | 3'Flank (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- PGR | c.*8C>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- PKN1 | c.1885-15C>G | Intron (SNP) | VAF 50/105 reads (48%) | catalogued as rs1485888754; called by muse, mutect2, varscan2
- PPP2CA | c.*3139C>G | 3'UTR (SNP) | VAF 41/66 reads (62%) | called by muse, mutect2, varscan2
- PPP4R1L | n.979+265A>C | Intron (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- PYGO1 | c.*2928C>T | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- RIMS1 | chr6:72401873 T>C | 3'Flank (SNP) | VAF 6/41 reads (15%) | called by mutect2, varscan2
- RYR2 | c.1708+1975G>C | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-3140G>T | Intron (SNP) | VAF 59/134 reads (44%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3479-421T>G | Intron (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- SHPRH | c.*1031G>A | 3'UTR (SNP) | VAF 28/31 reads (90%) | called by muse, mutect2, varscan2
- SLFNL1 | c.-118-398T>G | Intron (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627429 T>A | 3'Flank (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- SMYD3 | c.531+989T>C | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- SNORD116-26 | n.33C>T | RNA (SNP) | VAF 16/40 reads (40%) | catalogued as rs774275910; called by muse, varscan2
- SOS2 | c.*374T>G | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- SPIN1 | c.*2372C>A | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- SYNPO2 | c.*109_*110del | 3'UTR (DEL) | VAF 12/35 reads (34%) | called by pindel, varscan2
- TMA16 | chr4:163494510 T>C | 5'Flank (SNP) | VAF 60/131 reads (46%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.*1093C>A | 3'UTR (SNP) | VAF 18/668 reads (3%) | called by muse, mutect2
- TP63 | c.1350-4959G>A | Intron (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- TPO | c.*398C>T | 3'UTR (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- TTF1 | c.*113G>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- YPEL5 | c.*1480A>T | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- ZGRF1 | c.4697+46A>C | Intron (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2
- ZNF425 | c.*751T>A | 3'UTR (SNP) | VAF 65/158 reads (41%) | called by muse, mutect2, varscan2
